Surgical pathology report (de-identified scan), TCGA case TCGA-R5-A7ZI, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-R5-A7ZI-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) STOMACH, ANTRUM, BIOPSY:

Antral type mucosa with chemical/reactive gastropathy.

No Helicobacter pylori-like organisms (H&E stain), tumor or intestinal metaplasia identified.

(B) STOMACH, BIOPSY:

FRAGMENTS OF INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA. (SEE COMMENT)

COMMENT

The immunohistochemical stains for EBV will be reported as an addendum.

GROSS DESCRIPTION

(A) ANTRAL NODULE – Four tan-pink soft tissue fragments have an aggregate dimension of 0.5 x 0.5 x 0.4 cm and are submitted in toto in A.

(B) GASTRIC MASS – Four tan-red soft tissue fragments have an aggregate dimension of 0.9 x 0.8 x 0.5 cm and are submitted in toto in B.

CLINICAL HISTORY

Gastric cancer

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

CLCF ICD-O-3

Adenocarcinoma, diffuse type
path 8145/3

Adenocarcinoma NOS
8140/3

Site Stomach NOS
C16.9

W 10/9/13

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

COMMENT

The in situ hybridization for EBV performed on part B (stomach) is negative.

Entire report and diagnosis completed by:

-----END OF REPORT-----

*Per TSS, dx discrepancy from
Stataw TC6A tumor to be
adenocarcinoma, diffuse type.*

Criteria	W 9/30/13	Yes	No

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:

Person ID: N/A

Study/Site: TCGA Stomach adenocarcinoma - adenocarcinoma)

(Stomach

Age: N/A

Event: PathDiscrepancy

Date of Birth:

Interviewer:

Sex: F

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

POORLY DIFFERENTIATED
ADENOCARCINOMA

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

Adenocarcinoma
Diffuse Type

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

The pathologists at always use the gastric cancer classification as intestinal and diffuse (which is so as per TCGA).

do not

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file f2629216-6555-48dd-b6af-7dd9accf3e92 (TCGA-R5-A7ZI.37439CF6-7693-4897-ADBD-A620A0565180.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).